Gene-level copy-number profile of tumor specimen TCGA-AJ-A6NU-01A from TCGA case TCGA-AJ-A6NU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 64.3 years (23,498 days).
Specimen TCGA-AJ-A6NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.5f3a5f82-4af3-443e-92a4-63812471c90e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A6NU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0227b026-857a-46c3-948d-9ac3d730aa74

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,489; copy number 2: 43,496; copy number 3: 1,561; copy number 4: 108; copy number 5: 1,132; copy number 9: 11; copy number 10: 2; copy number 15: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A6NU-01A-11D-A34P-01): tumor purity 0.42, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,159 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–163,509,595, 885 genes, copy number 5–9 (broad region; genes not listed).
- chr5:38,556,765–38,671,216, 1 gene, copy number 5 (within-gene range 2–5): LIFR-AS1.
- chr17:39,603,536–39,864,312, 14 genes, copy number 15 (within-gene range 2–15): NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr19:32,025,808–37,719,188, 257 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:61,077,224–61,083,750, 2 genes, copy number 10: AL121910.1, LINC01718.

Autosomal genes at a single copy (total copy number 1): 13,489. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
